TCGA case TCGA-DX-AB36 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6a25aeca-126b-408b-ae13-e7df29f552b4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age: 90 years or older (exact value withheld by GDC); Vital status: Dead; Days to death: 1,168 days (3.2 years).

Diagnoses (2)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C49.3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of thorax; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2008; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: No; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4.3; Tumor length measurement: 8.1; Tumor width measurement: 4.5.
2. Liposarcoma, well differentiated: ICD-O-3 morphology code: 8851/3; Tissue or organ of origin: Thorax, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Days to diagnosis: -3,991 days (-10.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,168.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-AB36-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,500 mg.
  Slide TCGA-DX-AB36-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-AB36-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-AB36-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; New tumor event diagnosis indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Chest - Chest wall.
- Primary pathology: Margin status: Positive; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No; Well diff liposarc prior diagnosis indicator: Yes.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Chest wall; Other malignancy histological type: Well differentiated liposarcoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Excision.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,825 days; disease-specific survival: event status not recorded, 1,825 days; progression-free interval: no event (censored), 1,825 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-AB36-01A-11D-A416-01): tumor purity 0.99, ploidy 2.04, whole-genome doublings 0.
